Gene-level copy-number profile of tumor specimen TCGA-13-0791-02A from TCGA case TCGA-13-0791, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.5 years (21,380 days).
Specimen TCGA-13-0791-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.2560280e-62b8-4067-a7e4-8df8ac0c269a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0791-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 425 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second ASCAT2 file.
https://portal.gdc.cancer.gov/files/a8778db8-59f9-4aa0-88c1-dd11804883a7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 551; copy number 1: 696; copy number 2: 14,593; copy number 3: 19,575; copy number 4: 15,692; copy number 5: 4,317; copy number 6: 3,009; copy number 7: 525; copy number 8: 386; copy number 9: 269; copy number 10: 309; copy number 11: 44; copy number 12: 195; copy number 13: 1; copy number 14: 9; copy number 15: 17; copy number 18: 10.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr1:152,786,214–152,788,426, 1 gene: LCE1E.
- chr15:30,344,307–30,723,495, 27 genes (within-gene range 0–2): AC019322.4, Y_RNA, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2, AC127502.1, AC127502.2, AC127502.3, AC026150.2, AC026150.1, GOLGA8Q, RN7SL796P, DNM1P50, ULK4P2, U8, GOLGA8H, AC026150.3, RN7SL628P, AC091057.3, AC091057.2, ARHGAP11B, AC091057.5, AC091057.6.
- chr15:30,673,750–30,673,843, 1 gene: Y_RNA.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,624 genes in 59 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,014,028–16,352,480, 15 genes, copy number 7 (within-gene range 4–7): HSPB7, CLCNKA, AL355994.2, CLCNKB, FAM131C, EPHA2, AL451042.2, AL451042.1, ARHGEF19-AS1, ARHGEF19, ANO7L1, AL109627.1, CPLANE2, MT1XP1, FBXO42.
- chr1:35,713,877–39,817,460, 124 genes, copy number 8–10 (broad region; genes not listed).
- chr1:76,867,480–78,171,237, 34 genes, copy number 7: ST6GALNAC5, MIR7156, AL035409.2, AL035409.1, PIGK, AC113935.1, AC093433.1, AC093433.2, AK5, AC095030.1, RNU7-8P, AC093575.1, ZZZ3, RNA5SP20, RN7SL370P, USP33, ACTG1P21, MIGA1, RNA5SP21, AC138392.1, NSRP1P1, HSPE1P25, NEXN-AS1, NEXN, FUBP1, DNAJB4, GIPC2, AC103591.3, AC103591.4, AC103591.2, RNU6-1102P, AC103591.1, RNA5SP22, RNFT1P2.
- chr1:205,657,851–205,896,082, 9 genes, copy number 7 (within-gene range 4–7): SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29, AC119673.1, SLC41A1, AC119673.2, PM20D1.
- chr2:88,857,161–89,254,015, 40 genes, copy number 12: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr3:148,791,102–152,679,450, 97 genes, copy number 7 (broad region; genes not listed).
- chr3:166,160,021–169,709,765, 45 genes, copy number 10–12: MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3.
- chr4:65,669,961–66,150,012, 7 genes, copy number 7: EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1.
- chr4:168,755,816–170,482,195, 29 genes, copy number 9: RPL9P16, AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1, NEK1, AC084724.1, CLCN3, HPF1, PTGES3P3, AC079768.1, AC079768.3, AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612, LINC02512, AC074255.1.
- chr5:35,852,695–36,196,849, 12 genes, copy number 8: IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P.
- chr5:74,111,690–75,362,101, 26 genes, copy number 7–8: LINC01331, LINC01335, RN7SL814P, LINC01333, LINC01332, ENC1, HEXB, GFM2, RNU6-658P, NSA2, FAM169A, RNU6-1330P, AC093214.1, AC010501.2, AC010501.1, AC116337.4, AC116337.3, AC116337.1, AC116337.2, RPL27AP5, AC093259.1, GCNT4, ANKRD31, SUMO2P5, AC008897.2, HMGCR.
- chr5:133,574,829–134,752,157, 34 genes, copy number 8: AC010608.2, AC005178.1, WSPAR, C5orf15, VDAC1, AC008608.2, AC008608.1, TCF7, SKP1, AC104109.3, PPP2CA, AC104109.4, MIR3661, AC104109.2, AC104109.1, CDKL3, UBE2B, AC109454.4, AC109454.2, CDKN2AIPNL, AC109454.1, AC109454.3, AC005355.1, RNU6-456P, LINC01843, RN7SL541P, AC005355.2, JADE2, SAR1B, RNU6-1311P, SEC24A, RNU6-1164P, RNU6-757P, CAMLG.
- chr6:26,402,237–27,407,996, 41 genes, copy number 9: BTN3A1, BTN2A3P, BTN3A3, BTN2A1, BTN1A1P1, BTN1A1, RNU6-502P, HCG11, HMGN4, AL121936.1, ABT1, AL513548.3, AL513548.2, ZNF322, AL513548.4, AL513548.1, GUSBP2, POM121L6P, LINC00240, AL133255.1, AL590062.1, VN1R12P, VN1R13P, VN1R11P, RNU2-62P, AL021807.1, H2BC11, H2AC11, H4C9, H2BC12, H2AC12, MIR3143, RPL10P2, PRSS16, AL021808.1, POM121L2, VN1R10P, ZNF204P, ZNF391, AL031118.1, MCFD2P1.
- chr6:72,621,792–73,198,853, 6 genes, copy number 8 (within-gene range 4–8): KCNQ5, MIR4282, KNOP1P4, PGAM1P10, KCNQ5-AS1, RBPMS2P1.
- chr7:20,217,577–23,832,513, 64 genes, copy number 7–18 (within-gene range 6–18) (broad region; genes not listed).
- chr7:77,043,721–77,995,171, 17 genes, copy number 8–12: AC007000.3, FAM185BP, AC007000.1, CCDC146, FGL2, AC098851.1, GSAP, AC004921.1, GCNT1P5, AC004921.2, PTPN12, APTR, RSBN1L, TMEM60, PHTF2, Y_RNA, AC004990.1.
- chr7:79,768,028–81,432,796, 17 genes, copy number 9: GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2.
- chr8:67,952,046–68,819,023, 9 genes, copy number 7 (within-gene range 5–7): PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269.
- chr8:123,041,968–124,372,692, 42 genes, copy number 8 (within-gene range 4–8): TBC1D31, HMGB1P19, AC068228.3, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65.
- chr10:11,679,675–12,250,589, 13 genes, copy number 7: AL512631.1, ECHDC3, PROSER2, PROSER2-AS1, UPF2, RNU6-1095P, DHTKD1, RNU6-88P, SEC61A2, MIR548AK, NUDT5, CDC123, AL512770.1.
- chr10:42,209,990–42,834,937, 24 genes, copy number 7 (within-gene range 5–7): AL031601.1, AL031601.2, PABPC1P8, BX322639.1, CCNYL2, AL391099.1, LINC00839, ZNF37BP, FXYD6P1, EIF3LP2, ZNF33B, AL022345.3, AL022345.1, AL022345.2, RNU6-1170P, AL022345.4, LINC01518, VN1R54P, CUBNP1, LINC02632, RSU1P1, DUXAP3, AL022344.1, BMS1.
- chr10:61,406,642–64,826,579, 39 genes, copy number 7–13: TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1, AC013287.1, RPL7AP50, AC012558.1, DBF4P1, RPL17P35, CYP2C61P, ANXA2P3.
- chr10:71,711,701–73,247,255, 49 genes, copy number 10 (within-gene range 1–10): C10orf105, VSIR, MIR7152, PSAP, RNU7-38P, AC073370.1, CHST3, AC022392.1, SPOCK2, ASCC1, AL607035.1, RPL15P14, ANAPC16, Y_RNA, DDIT4, DDIT4-AS1, DNAJB12, MICU1, RNU6-805P, AC091769.1, SNX19P4, AL513185.1, AL513185.2, RN7SL840P, HMGN2P34, AL513185.3, Y_RNA, MCU, MIR4676, AC016542.3, AC016542.2, AC016542.1, OIT3, NPM1P24, PLA2G12B, RPL17P50, P4HA1, AL731563.1, AL731563.2, Y_RNA, AL731563.3, NUDT13, AC016394.1, SNORA11F, ECD, FAM149B1, DNAJC9, Y_RNA, EIF4A2P2.
- chr10:74,120,255–77,638,369, 49 genes, copy number 8–10 (within-gene range 1–12): AP3M1, ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1, AC013286.1, AC024603.1, AC013738.1, ATP5MC1P8, KCNMA1, KCNMA1-AS1.
- chr10:77,433,572–81,137,335, 92 genes, copy number 7–12 (broad region; genes not listed).
- chr11:100,641,975–106,469,296, 99 genes, copy number 7–14 (broad region; genes not listed).
- chr11:121,101,243–121,633,763, 8 genes, copy number 8 (within-gene range 6–8): TECTA, AP001124.1, RPS4XP12, SC5D, BMPR1AP2, AP002365.1, AP000977.1, SORL1.
- chr11:128,880,325–133,532,519, 61 genes, copy number 9–14 (within-gene range 6–14) (broad region; genes not listed).
- chr12:33,374,238–34,249,958, 18 genes, copy number 7: SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr13:51,584,455–54,986,720, 58 genes, copy number 9: WDFY2, RNY1P6, RN7SL413P, ATP5PBP1, AL162377.3, DHRS12, AL162377.1, TMEM272, CCDC70, CTAGE3P, AL162377.2, ATP7B, FABP5P2, ALG11, UTP14C, NEK5, AL139082.1, NEK3, MRPS31P5, AL158066.1, THSD1P1, AL158066.2, TPTE2P2, LINC02333, THSD1, RNY4P24, VPS36, AL359513.1, CKAP2, LINC00345, AL137058.1, AL137058.3, AL137058.2, MRPS31P4, HNRNPA1L2, SUGT1-DT, SUGT1, CNMD, MIR759, PPIAP26, PCDH8, OLFM4, LINC01065, AL136359.1, PCDH8P1, AL356295.1, RN7SL618P, AL450423.2, AL450423.1, ZNF646P1, LINC00558, LINC00458, AL356052.1, MIR1297, RPL13AP25, AL442636.1, AL512655.1, AL390964.1.
- chr13:67,577,624–71,297,235, 28 genes, copy number 9: AL512452.1, BCRP9, NPM1P22, OR7E111P, OR7E33P, AL590027.1, ELL2P3, HNRNPA1P18, RPL37P21, RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4, SNRPFP3, LINC00383, SRSF1P1, KLHL1, RNY3P10, PSMC1P13, ATXN8OS, AL160391.1, RNU6-54P, AL445264.1, MTCL1P1, LINC00348, RABEPKP1.
- chr13:72,453,902–73,113,018, 16 genes, copy number 9: AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P.
- chr14:35,430,260–36,068,261, 15 genes, copy number 8 (within-gene range 5–8): DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1.
- chr14:36,533,506–36,679,362, 6 genes, copy number 9: PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9.
- chr14:105,736,343–106,318,236, 93 genes, copy number 8 (broad region; genes not listed).
- chr20:31,257,664–32,743,567, 67 genes, copy number 8–12 (broad region; genes not listed).
- chr20:38,210,503–39,233,836, 41 genes, copy number 7: KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173, PPP1R16B, RN7SL116P, FAM83D, AL023803.2, AL023803.1, DHX35, AL023803.3, NPM1P19, LINC01734, AL035251.1.
- chr20:44,389,624–45,948,023, 84 genes, copy number 10 (broad region; genes not listed).
- chr22:37,125,843–37,726,503, 26 genes, copy number 10 (within-gene range 4–10): IL2RB, Z82188.2, C1QTNF6, SSTR3, Z82188.1, RAC2, CYTH4, ELFN2, Z94160.1, ELFN2, Z94160.2, MFNG, CARD10, AL022315.1, CDC42EP1, LGALS2, Metazoa_SRP, GGA1, SH3BP1, Z83844.2, PDXP-DT, PDXP, RN7SL385P, LGALS1, NOL12, Z83844.1.
- chr22:40,043,068–40,682,814, 15 genes, copy number 7: Z83847.1, TNRC6B, RPL7P52, ADSL, AL022238.3, SGSM3, SGSM3-AS1, MRTFA, AL022238.2, AL022238.1, MRTFA-AS1, COX6B1P3, RPL4P6, GAPDHP37, MCHR1.

Autosomal genes at a single copy (total copy number 1): 696. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
